Gene-level copy-number profile of tumor specimen TCGA-AZ-4684-01A from TCGA case TCGA-AZ-4684, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 50.0 years (18,252 days).
Specimen TCGA-AZ-4684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.13cf3806-22ff-490f-83bc-d421f2da5fab.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AZ-4684-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 369 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5db703c-43e9-4c33-b725-a21c44ddd2ea

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,373; copy number 2: 8,495; copy number 3: 11,470; copy number 4: 26,365; copy number 5: 4,624; copy number 6: 3,886; copy number 7: 912; copy number 8: 104; copy number 9: 39; copy number 10: 65; copy number 11: 506; copy number 12: 9; copy number 13: 19; copy number 15: 36; copy number 16: 292; copy number 17: 41; copy number 18: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AZ-4684-01): tumor purity 0.47, ploidy 3.65, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,024 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,795,527–43,104,497, 195 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:46,028,804–46,974,617, 19 genes, copy number 11: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4.
- chr8:60,141,821–63,470,205, 48 genes, copy number 11: SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P.
- chr8:65,644,734–67,407,072, 39 genes, copy number 9: MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1.
- chr8:67,952,046–71,228,629, 48 genes, copy number 11–13 (within-gene range 4–13): PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, AC120194.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA.
- chr8:76,406,654–77,014,028, 10 genes, copy number 11 (within-gene range 8–11): LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18.
- chr8:79,259,402–81,924,348, 70 genes, copy number 11 (broad region; genes not listed).
- chr8:82,098,451–82,160,577, 1 gene, copy number 11 (within-gene range 8–11): LINC02839.
- chr8:85,833,377–91,398,155, 67 genes, copy number 10–16 (broad region; genes not listed).
- chr8:91,594,965–91,595,241, 1 gene, copy number 10: RN7SKP231.
- chr8:98,904,603–110,349,607, 200 genes, copy number 10–18 (broad region; genes not listed).
- chr8:112,222,928–113,436,939, 1 gene, copy number 12 (within-gene range 4–12): CSMD3.
- chr8:112,643,493–141,060,596, 325 genes, copy number 10–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 473. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
